Gene-level copy-number profile of tumor specimen ALCH-B3KK-TTP1-A from ALCHEMIST case ALCH-B3KK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.5 years (27,207 days).
Specimen ALCH-B3KK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2b805324-9e8f-4a48-bba3-b287718b80fc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3KK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/99c67add-062a-4732-b2c9-bb11e2cdcea4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 5,051; copy number 2: 52,726; copy number 3: 451; copy number 4: 233; copy number 5: 263; copy number 6: 75; copy number 8: 3; copy number 10: 26; copy number 16: 1; copy number 17: 3.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,478,775–41,484,683, 1 gene: EDN2.
- chr3:49,857,988–49,869,935, 2 genes: CAMKV, RN7SL217P.
- chr3:129,314,771–129,326,225, 3 genes: H1-10, H1-10-AS1, NUP210P3.
- chr3:129,528,639–129,535,344, 1 gene: RHO.
- chr4:49,096–50,124, 1 gene: BNIP3P41.
- chr4:672,436–689,271, 3 genes: ATP5ME, MYL5, SLC49A3.
- chr6:10,474,500–10,478,502, 1 gene: LINC02522.
- chr9:132,161,676–132,244,526, 1 gene: NTNG2.
- chr12:164,664–182,399, 2 genes (within-gene range 0–3): AC026369.2, AC007406.3.
- chr12:193,036–194,130, 1 gene (within-gene range 0–2): AC007406.1.
- chr14:93,067,452–93,072,152, 1 gene (within-gene range 0–2): ITPK1-AS1.
- chr14:99,324,799–99,332,015, 1 gene: AL132819.1.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:55,728,115–55,793,960, 2 genes: CES1P2, CES1P1.
- chr18:12,056,676–12,057,822, 1 gene: AP002414.1.
- chr19:19,512,418–19,536,076, 3 genes (within-gene range 0–1): TSSK6, NDUFA13, AC011448.1.
- chr19:19,538,248–19,618,693, 4 genes (within-gene range 0–2): CILP2, PBX4, PHF5CP, AC002306.1.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.
- chr22:46,053,869–46,113,928, 1 gene (within-gene range 0–2): MIRLET7BHG.
- chr22:46,067,356–46,113,768, 5 genes: AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 369 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes, copy number 6: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:55,738,017–55,817,157, 1 gene, copy number 5 (within-gene range 3–5): DDX4.
- chr5:55,777,469–56,382,075, 19 genes, copy number 5: RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17.
- chr16:28,700,294–28,777,534, 4 genes, copy number 5–16: CDC37P1, AC145285.5, NPIPB9, AC145285.7.
- chr21:44,217,014–44,244,993, 3 genes, copy number 17: ICOSLG, AP001059.2, AP001059.1.
- chr22:15,282,557–15,829,984, 26 genes, copy number 10 (within-gene range 4–10): AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1.
- chr22:20,338,805–21,371,945, 63 genes, copy number 6 (broad region; genes not listed).
- chr22:27,102,766–35,553,999, 241 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
